Somatic mutation profile of tumor specimen TCGA-2G-AAFI-01A (aliquot TCGA-2G-AAFI-01A-21D-A42Y-10) from TCGA case TCGA-2G-AAFI, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 41.0 years (14,976 days).
Specimen TCGA-2G-AAFI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baec1e6e-5fa7-4009-b66a-9ed832091219.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFI-10A (Blood Derived Normal), aliquot TCGA-2G-AAFI-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7767798b-106a-422f-92c5-81a5363ee829

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRC2 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs541473425; called by muse, mutect2, varscan2
- ADNP | c.1743C>A p.Y581* | Nonsense Mutation (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- BBS9 | c.1698dup p.A567Cfs*6 (on ENST00000242067 / NM_001348036.1; = p.A527Cfs*6 on NM_014451.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- H4C1 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- MYH15 | c.1338G>C p.R446S | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- PRICKLE2 | c.1313C>T p.S438F (on ENST00000295902; = p.S382F on NM_198859.4) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MYPN | c.213A>G p.E71= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as rs1192337648; called by muse, mutect2
- NUTM2B | c.2592C>T p.D864= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2
- RTKN2 | c.1773G>A p.R591= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as COSV59523806; called by muse, mutect2, varscan2
